Somatic mutation profile of tumor specimen TCGA-DK-A1A5-01A (aliquot TCGA-DK-A1A5-01A-11D-A13W-08) from TCGA case TCGA-DK-A1A5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 79.7 years (29,111 days).
Specimen TCGA-DK-A1A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d566ea-51d7-48b9-8487-14cc177f315f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1A5-10A (Blood Derived Normal), aliquot TCGA-DK-A1A5-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9485c3e3-463e-45aa-9167-61649d3ec711

The open-access MAF lists 295 somatic variants for this specimen: 213 protein-altering or splice-affecting, 78 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 78, Nonsense Mutation 13, Frame Shift Del 3, Splice Site 2, Intron 2, RNA 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 45/87 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54386569; called by muse, mutect2, varscan2
- AC023055.1 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.742); catalogued as rs937556788, COSV60243644; called by muse, mutect2, varscan2
- ACTN4 | c.2681G>A p.G894D | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as rs1568754170, COSV53148076; called by muse, mutect2, varscan2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- AGL | c.3955G>C p.A1319P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs1268881357, COSV54055668; called by muse, mutect2, varscan2
- AIFM3 | c.1755G>A p.V585= | Splice Region (SNP) | VAF 17/43 reads (40%) | catalogued as COSV53149351; called by muse, mutect2, varscan2
- AKAP9 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs1423223603, COSV62352247; called by muse, mutect2, varscan2
- AMOTL1 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1049662718, COSV54414684, COSV54417171; called by muse, mutect2, varscan2
- AMY2A | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770253522, COSV70214692; called by muse, mutect2, varscan2
- ANK3 | c.10152G>C p.Q3384H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as rs778769380, COSV55062763; called by muse, mutect2, varscan2
- ANKRD40 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV53333065; called by muse, mutect2, varscan2
- APOL2 | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV50772465; called by muse, varscan2
- ARHGAP32 | c.5422G>A p.E1808K (on ENST00000310343 / NM_001378025.1; = p.E1459K on NM_014715.4) | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV59851960; called by muse, mutect2, varscan2
- ASB2 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV60113387; called by muse, mutect2, varscan2
- ASPG | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV71933996; called by muse, mutect2, varscan2
- ATAD2 | c.4111G>T p.D1371Y | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54883986; called by muse, mutect2, varscan2
- ATAD2 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54883997; called by mutect2, varscan2
- ATXN3L | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66076006; called by muse, mutect2, varscan2
- B2M | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs148494241, COSV62562854; called by muse, mutect2, varscan2
- B3GALT4 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233066412, COSV65851923; called by muse, mutect2, varscan2
- BMPER | c.1929C>G p.I643M | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV51825705; called by muse, mutect2, varscan2
- BRCA2 | c.6241G>C p.E2081Q | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV66458236; called by muse, mutect2, varscan2
- BTN2A1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV57005037; called by muse, mutect2, varscan2
- C1D | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV63413656; called by muse, mutect2, varscan2
- CADPS | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV51891605, COSV99339182; called by muse, mutect2, varscan2
- CCDC73 | c.3127C>G p.L1043V | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV58801557; called by muse, mutect2, varscan2
- CD86 | c.677G>A p.R226Q (on ENST00000330540 / NM_175862.5; = p.R220Q on NM_006889.4) | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs772981720, COSV52608439; called by muse, mutect2, varscan2
- CDK13 | c.3992C>G p.S1331C | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV51703302; called by muse, mutect2, varscan2
- CENPF | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV65273668, COSV65276838; called by muse, mutect2, varscan2
- CEP131 | c.2821G>C p.E941Q (on ENST00000269392 / NM_001319228.2; = p.E938Q on NM_014984.4) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53954666; called by muse, mutect2, varscan2
- CEP131 | c.2659G>A p.E887K (on ENST00000269392 / NM_001319228.2; = p.E884K on NM_014984.4) | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV53951538, COSV53954678; called by muse, varscan2
- COL4A1 | c.2741C>T p.S914L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as COSV65428667; called by muse, mutect2, varscan2
- COL5A1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765170704, COSV65667693; called by muse, mutect2, varscan2
- CRIM1 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV54868671, COSV99753574; called by muse, varscan2
- CTRL | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV52124230; called by muse, mutect2, varscan2
- CYP4F12 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs773893383, COSV61172924; called by muse, mutect2, varscan2
- DAGLB | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 112/206 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV51705649; called by muse, mutect2, varscan2
- DDR2 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63372553; called by muse, mutect2, varscan2
- DHDDS | c.434A>T p.Y145F | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV52577582; called by muse, mutect2, varscan2
- DNAH7 | c.11854G>C p.D3952H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201407001; called by muse, mutect2, varscan2
- DNAI2 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.405); catalogued as COSV56760838; called by muse, mutect2, varscan2
- DRG2 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56728794; called by muse, mutect2, varscan2
- DRG2 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs765487914, COSV56728800; called by muse, mutect2, varscan2
- DSCAM | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68031506; called by muse, mutect2, varscan2
- EDC4 | c.2983G>C p.E995Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV59303293; called by muse, mutect2, varscan2
- EDEM1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56582931; called by muse, mutect2, varscan2
- EIF4A3 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV53920882, COSV53921841; called by muse, mutect2
- EP300 | c.4227G>C p.L1409F | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV54338652; called by muse, mutect2
- EPAS1 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1021730994, COSV55388396, COSV99763266; called by muse, mutect2, varscan2
- EPB41 | c.2454G>C p.K818N (on ENST00000343067 / NM_001166005.2; = p.K542N on NM_004437.4) | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58050849; called by muse, mutect2, varscan2
- EPB41L1 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as COSV52440978; called by muse, mutect2, varscan2
- EPC1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53927917; called by muse, mutect2, varscan2
- EPG5 | c.6201G>C p.Q2067H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV56347545, COSV99956844; called by muse, mutect2, varscan2
- ERBB2 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 5548/5746 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.43); catalogued as COSV54067264; called by mutect2, varscan2
- ERC1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61697329; called by muse, mutect2, varscan2
- F2RL1 | c.465C>G p.F155L | Missense Mutation (SNP) | VAF 120/432 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1186871864, COSV56996220; called by muse, mutect2, varscan2
- FANCA | c.4201C>G p.L1401V | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs566927763, COSV57070602; called by muse, mutect2, varscan2
- FANCD2 | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.167); catalogued as COSV55042091; called by muse, mutect2, varscan2
- FASN | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs774656123, COSV60757968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXO42 | c.2097G>C p.Q699H | Missense Mutation (SNP) | VAF 153/338 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV65046330; called by muse, mutect2, varscan2
- FBXO42 | c.1922G>A p.C641Y | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV65046333; called by muse, mutect2, varscan2
- FOCAD | c.2270C>G p.S757C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as rs1268602854, COSV100620701, COSV58103893; called by muse, mutect2, varscan2
- FOXM1 | c.954G>C p.L318F | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs769684541, COSV61206771; called by muse, mutect2, varscan2
- FRYL | c.7834G>A p.E2612K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.046); catalogued as COSV51954023; called by muse, mutect2, varscan2
- FZD6 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763949530, COSV62470502; called by muse, mutect2, varscan2
- GATAD2B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 210/562 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV64085099; called by muse, mutect2, varscan2
- GGA1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454217253, COSV100289824, COSV99044545; called by muse, mutect2
- GIMAP2 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as rs1175620215; called by muse, mutect2, varscan2
- GLI2 | c.1240G>C p.E414Q (on ENST00000361492 / NM_001374353.1; = p.E431Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58046693; called by muse, mutect2, varscan2
- GMIP | c.2487G>C p.Q829H | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as COSV52558259; called by muse, mutect2, varscan2
- GPR155 | c.983G>C p.G328A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.779); catalogued as COSV55037087, COSV55040533; called by muse, mutect2, varscan2
- GPR158 | c.2199G>T p.M733I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100893600, COSV66276621; called by muse, mutect2, varscan2
- GPRC5D | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.585); catalogued as rs374734710, COSV57432875, COSV57433062; called by muse, mutect2, varscan2
- GSE1 | c.3196C>G p.P1066A | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53674005; called by muse, mutect2, varscan2
- H2AC11 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV60362384; called by muse, mutect2, varscan2
- HAAO | c.677T>A p.V226E | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0.313); catalogued as COSV54312009; called by muse, mutect2, varscan2
- HECW1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1272735976, COSV67837401; called by muse, mutect2, varscan2
- HGF | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99736021; called by muse, mutect2, varscan2
- HHIPL2 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 88/126 reads (70%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as COSV58566325; called by muse, varscan2
- HIVEP1 | c.2944T>A p.C982S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65103567; called by muse, mutect2, varscan2
- HMGB4 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as COSV53906224, COSV53974767; called by muse, mutect2, varscan2
- IL10RB | c.102C>G p.F34L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.14); catalogued as COSV51616753; called by muse, mutect2, varscan2
- IL17RC | c.898G>T p.E300* (on ENST00000295981 / NM_153461.4; = p.E214* on NM_032732.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 101/189 reads (53%) | catalogued as COSV99925623; called by muse, mutect2, varscan2
- INO80D | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68957931, COSV68959531; called by muse, mutect2, varscan2
- INSYN1 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 92/526 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV65837623; called by muse, mutect2, varscan2
- IQCE | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs201827624; called by muse, mutect2, varscan2
- IQGAP3 | c.4774C>T p.H1592Y | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1381538252, COSV63253189; called by muse, mutect2, varscan2
- ITGB8 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV56011476; called by muse, mutect2, varscan2
- KALRN | c.6315G>A p.M2105I (on ENST00000360013 / NM_001024660.4; = p.M408I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/223 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV52260754; called by muse, mutect2, varscan2
- KCNT1 | c.416C>T p.S139L (on ENST00000488444; = p.S158L on NM_020822.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751075368, COSV53704218, COSV53706147; called by muse, varscan2
- KDM4A | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 148/330 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV53517053; called by muse, mutect2, varscan2
- KIAA1217 | c.4814A>C p.Y1605S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56819872; called by muse, mutect2, varscan2
- KIF21A | c.3893C>T p.S1298L (on ENST00000361418 / NM_001378440.1; = p.S1285L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV62766562; called by muse, mutect2, varscan2
- KIR3DL1 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 242/345 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV100428585; called by muse, mutect2, varscan2
- KLHL7 | c.478G>A p.E160K (on ENST00000339077 / NM_001031710.3; = p.E112K on NM_018846.5) | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV59162913; called by muse, mutect2, varscan2
- KMT5B | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58568134; called by muse, mutect2, varscan2
- KRT71 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57291904; called by muse, mutect2, varscan2
- KRTAP13-1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV62663863; called by muse, mutect2, varscan2
- LRP2 | c.2212G>A p.G738R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV55561010; called by muse, mutect2, varscan2
- LYSMD3 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV60057770; called by muse, mutect2, varscan2
- MAGED2 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 45/58 reads (78%) | catalogued as COSV54497890; called by muse, mutect2, varscan2
- MAJIN | c.474-1G>C p.X158_splice | Splice Site (SNP) | VAF 68/129 reads (53%) | catalogued as COSV54164392, COSV54164797; called by muse, mutect2, varscan2
- MAP3K5 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV62889504; called by muse, mutect2, varscan2
- MARCHF6 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56884120; called by muse, mutect2, varscan2
- MARCO | c.1417A>G p.K473E | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as COSV59056377; called by muse, mutect2, varscan2
- MMP15 | c.193C>G p.Q65E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV54680588; called by muse, mutect2, varscan2
- MUC5AC | c.401G>C p.S134T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.43); catalogued as COSV62254744; called by muse, mutect2, varscan2
- MYOT | c.1366del p.V456Ffs*9 | Frame Shift Del (DEL) | VAF 39/161 reads (24%) | catalogued as COSV51794530; called by mutect2, pindel, varscan2
- NANOG | c.365T>A p.L122H | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as COSV57552056; called by muse, mutect2, varscan2
- NCBP3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs372415582, COSV50108952; called by muse, mutect2, varscan2
- NDRG4 | c.74C>G p.S25C (on ENST00000570248 / NM_001378344.1; = p.S57C on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV50747576, COSV50749404; called by muse, mutect2, varscan2
- NECTIN1 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50603381, COSV99871958; called by muse, mutect2, varscan2
- NID2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV53499765; called by muse, mutect2, varscan2
- NIFK | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53535313; called by muse, mutect2, varscan2
- NIPBL | c.5254G>A p.D1752N | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.189); catalogued as rs765379536, COSV56958658; called by muse, mutect2, varscan2
- NNT | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV52927343; called by muse, mutect2, varscan2
- NRXN3 | c.2194G>T p.D732Y (on ENST00000335750 / NM_001330195.2; = p.D359Y on NM_004796.6) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59726855, COSV59777471; called by muse, mutect2, varscan2
- NUP160 | c.3953G>C p.G1318A | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV65855104; called by muse, mutect2, varscan2
- NUP205 | c.3697C>T p.H1233Y | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53662933; called by muse, mutect2, varscan2
- OR4A47 | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV71445186; called by muse, mutect2, varscan2
- OR4C6 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as COSV58605137; called by muse, mutect2, varscan2
- ORC1 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 38/142 reads (27%) | catalogued as COSV65364550; called by muse, mutect2, varscan2
- PCDHB8 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50792674; called by muse, mutect2, varscan2
- PCDHGB4 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.124); catalogued as COSV53913477; called by muse, mutect2, varscan2
- PDE7A | c.356G>C p.R119T (on ENST00000401827 / NM_001242318.3; = p.R93T on NM_002603.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV65153927; called by muse, mutect2, varscan2
- PIBF1 | c.2268G>C p.K756N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); catalogued as COSV58325809; called by muse, mutect2, varscan2
- PIK3CA | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.047); catalogued as COSV55956634; called by muse, mutect2, varscan2
- PLEKHG1 | c.2470C>G p.H824D | Missense Mutation (SNP) | VAF 137/307 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV62049201; called by muse, mutect2, varscan2
- PLEKHH2 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56757493; called by muse, mutect2, varscan2
- PML | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1567115731, COSV51448147, COSV99167161; called by muse, mutect2, varscan2
- POLN | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV67026405; called by muse, mutect2, varscan2
- PPEF2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54424552; called by muse, mutect2, varscan2
- PPL | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV62046161; called by muse, mutect2, varscan2
- PREX2 | c.1382G>C p.R461T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786138, COSV55805592; called by muse, mutect2, varscan2
- PRPF40A | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV68358529; called by muse, mutect2, varscan2
- PTH1R | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1278093318; called by muse, mutect2, varscan2
- PTPN9 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV60724883; called by muse, mutect2, varscan2
- PUM2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV57583526; called by muse, mutect2, varscan2
- RAD51AP2 | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67588576; called by muse, mutect2, varscan2
- RASGRF1 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV67250647; called by muse, mutect2, varscan2
- RELN | c.6639G>C p.L2213F | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59019444; called by muse, mutect2, varscan2
- RNF216 | c.433G>A p.E145K (on ENST00000425013 / NM_207116.3; = p.E202K on NM_207111.4) | Missense Mutation (SNP) | VAF 82/488 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.127); catalogued as rs769671024, COSV66291713; called by muse, mutect2, varscan2
- RNF5 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 311/877 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV61248193; called by muse, mutect2, varscan2
- RP1L1 | c.3385G>C p.E1129Q | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV66757755; called by muse, mutect2, varscan2
- RPGRIP1 | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV52853376; called by muse, mutect2, varscan2
- RPP40 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV60292503; called by muse, mutect2, varscan2
- RPS27A | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1407397994, COSV55052791; called by muse, mutect2, varscan2
- RTN2 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 161/241 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV55595164; called by muse, mutect2, varscan2
- RUFY1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs1172891335, COSV60162051; called by muse, varscan2
- SARS2 | c.267C>T p.I89= | Splice Region (SNP) | VAF 46/273 reads (17%) | catalogued as COSV55499409; called by muse, mutect2, varscan2
- SCNM1 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1290847836, COSV54861430; called by muse, mutect2, varscan2
- SETD2 | c.4885C>T p.H1629Y | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57431577; called by muse, mutect2, varscan2
- SIGLEC8 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV58472035, COSV58474761; called by muse, mutect2, varscan2
- SIX4 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.362); catalogued as COSV53669017, COSV53670695; called by muse, mutect2, varscan2
- SLC12A3 | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52637001; called by muse, mutect2, varscan2
- SLC25A15 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58557569; called by muse, mutect2, varscan2
- SLC34A1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs753995754, COSV60997768; called by muse, mutect2, varscan2
- SMARCA2 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV61810002; called by muse, mutect2, varscan2
- SSH2 | c.1308G>C p.M436I | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV52176568; called by muse, mutect2, varscan2
- ST18 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1262569260, COSV52501321; called by muse, varscan2
- ST18 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs867547514, COSV52490872; called by muse, mutect2, varscan2
- STAU1 | c.1294C>G p.Q432E (on ENST00000371856 / NM_001319135.1; = p.Q351E on NM_004602.3) | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.219); catalogued as rs1480210963, COSV61461368; called by muse, mutect2, varscan2
- STOM | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54418684; called by muse, mutect2, varscan2
- SYNE1 | c.18887G>A p.R6296K (on ENST00000367255 / NM_182961.4; = p.R6225K on NM_033071.3) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV55038282; called by muse, mutect2, varscan2
- SYNJ1 | c.3781G>A p.E1261K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV59152134; called by muse, mutect2, varscan2
- SYNM | c.3163G>A p.G1055R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs781868003, COSV50442899; called by muse, mutect2
- TAS1R1 | c.2328C>G p.F776L | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV59840240; called by muse, mutect2, varscan2
- TBC1D8B | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as COSV52181204; called by muse, mutect2, varscan2
- TBCC | c.882G>C p.W294C | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55130920; called by muse, varscan2
- TBCC | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV55130931; called by muse, varscan2
- TBCC | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV55130941; called by muse, mutect2, varscan2
- TFPI2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.266); catalogued as rs770380317, COSV55990401, COSV55992087; called by muse, mutect2, varscan2
- TMEM132D | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101396751, COSV70612388, COSV70614382; called by muse, mutect2, varscan2
- TP53BP1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 195/569 reads (34%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.93); catalogued as COSV55505002; called by muse, mutect2, varscan2
- TPR | c.4802C>T p.A1601V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768494040, COSV66603153; called by muse, mutect2, varscan2
- TRIM46 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as rs376526448; called by muse, mutect2, varscan2
- TRPC6 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.761); catalogued as COSV60258021; called by muse, mutect2, varscan2
- TTC3 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV61293518; called by muse, mutect2, varscan2
- TTC6 | c.1480C>T p.R494C (on ENST00000267368; = p.R1860C on NM_001310135.3) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374277390; called by muse, mutect2, varscan2
- TXNL1 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV54180242; called by muse, mutect2, varscan2
- UBE3B | c.2942G>A p.R981K | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV61076072; called by muse, varscan2
- UNC13B | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65936731; called by muse, mutect2, varscan2
- VARS2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); catalogued as COSV52560151; called by muse, mutect2, varscan2
- WASHC2C | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV100314146; called by muse, mutect2, varscan2
- WDR62 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs1406367668; called by muse, mutect2
- WWP1 | c.1188A>T p.R396S | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55361745; called by muse, mutect2, varscan2
- XPNPEP3 | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64027704; called by muse, mutect2, varscan2
- YWHAB | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV53841574; called by muse, mutect2, varscan2
- ZC3H7A | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63270488; called by muse, mutect2, varscan2
- ZC4H2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.685); catalogued as rs751880978, COSV62004993; called by muse, mutect2, varscan2
- ZNF519 | c.768G>C p.K256N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV101645553, COSV73913500; called by muse, mutect2, varscan2
- ZNF594 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 184/328 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.394); catalogued as COSV68385833; called by muse, mutect2, varscan2
- ABCA10 | c.2501C>G p.S834* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- ACSM5 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- ADARB2 | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADGRA3 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- ADH1B | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARID5A | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 78/209 reads (37%) | called by muse, mutect2, varscan2
- BAZ2A | c.356dup p.Q120Tfs*20 | Frame Shift Ins (INS) | VAF 68/209 reads (33%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2
- KIAA0586 | c.3077C>G p.S1026* (on ENST00000619416 / NM_001244190.2; = p.S965* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- NEU2 | c.1075del p.Y359Tfs*11 | Frame Shift Del (DEL) | VAF 76/341 reads (22%) | called by mutect2, pindel, varscan2
- NPFFR2 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- POLD1 | c.3297C>G p.F1099L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2
- PPIA | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.528); called by muse, mutect2
- RASA4 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC17A4 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.012); called by muse, mutect2
- TAS2R50 | c.354_357del p.L119Ifs*2 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- VPS37B | c.681G>A p.M227I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by mutect2, varscan2
- ZBTB40 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | called by muse, varscan2
- ZNF518A | c.3890G>C p.R1297T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF84 | c.2101C>A p.H701N | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ABCA4 | c.5589G>A p.E1863= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV64675547; called by muse, mutect2, varscan2
- ABLIM2 | c.1662C>G p.L554= (on ENST00000341937 / NM_001130084.2; = p.L464= on NM_032432.5) | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ALPK3 | c.3120C>T p.L1040= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51936349; called by muse, mutect2, varscan2
- APOL2 | c.168G>C p.L56= | Silent (SNP) | VAF 58/227 reads (26%) | catalogued as COSV50772457, COSV50772473; called by muse, varscan2
- ARHGAP29 | c.384C>T p.L128= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1401479425, COSV53114314; called by muse, mutect2, varscan2
- ARHGAP39 | c.327G>A p.L109= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- BCLAF3 | c.2079C>T p.F693= (on ENST00000379682 / NM_001367774.1; = p.F664= on NM_198279.3) | Silent (SNP) | VAF 78/95 reads (82%) | catalogued as COSV61414483; called by muse, mutect2, varscan2
- BPIFA3 | c.15C>T p.L5= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs1449528543, COSV64926057; called by muse, mutect2, varscan2
- BTBD11 | c.2265G>A p.E755= (on ENST00000280758 / NM_001018072.2; = p.E292= on NM_001017523.2) | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV55030576; called by muse, mutect2, varscan2
- C1QTNF3 | c.18C>A p.L6= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV51469360; called by muse, mutect2, varscan2
- CASS4 | c.816C>G p.L272= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV64387435; called by muse, mutect2, varscan2
- CD163L1 | c.1353T>C p.D451= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1239339385, COSV58020483; called by muse, mutect2, varscan2
- CEP131 | c.2862G>C p.L954= (on ENST00000269392 / NM_001319228.2; = p.L951= on NM_014984.4) | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV53954655; called by muse, mutect2, varscan2
- CIT | c.771G>A p.P257= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs760427459, COSV55863599, COSV55875776; called by muse, mutect2, varscan2
- CLIC6 | c.1503C>T p.G501= (on ENST00000360731 / NM_001317009.2; = p.G483= on NM_053277.3) | Silent (SNP) | VAF 56/122 reads (46%) | catalogued as rs369846247; called by muse, mutect2, varscan2
- CYP4F2 | c.585C>T p.I195= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as COSV50002014; called by muse, mutect2, varscan2
- DNAH8 | c.4146T>C p.L1382= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV59464742; called by muse, mutect2, varscan2
- DNAJC11 | c.1449G>T p.V483= | Silent (SNP) | VAF 94/215 reads (44%) | catalogued as COSV50010459, COSV50011306; called by muse, mutect2, varscan2
- EHMT1 | c.3135C>T p.C1045= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs780620347, COSV71778140; called by muse, mutect2, varscan2
- ELAVL4 | c.147C>T p.I49= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1271121178, COSV63917754; called by muse, varscan2
- ELP2 | c.609C>G p.L203= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV60852974; called by muse, mutect2, varscan2
- ENTPD3 | c.702G>A p.K234= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs370656485, COSV57195519; called by muse, mutect2, varscan2
- FAT4 | c.6993C>A p.V2331= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58697862; called by muse, mutect2, varscan2
- FLT3 | c.2634G>A p.L878= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs779336061, COSV54061667; called by muse, mutect2
- G3BP1 | c.1029C>T p.F343= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV62366519; called by muse, mutect2, varscan2
- GDA | c.51C>T p.F17= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs752892598, COSV52994202; called by muse, mutect2, varscan2
- GLIS1 | c.327G>A p.L109= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV56552382; called by muse, mutect2, varscan2
- GOLGA4 | c.6258G>A p.K2086= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV62712151; called by muse, mutect2
- GREB1 | c.4926G>A p.V1642= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as COSV52191858; called by muse, mutect2, varscan2
- HECTD1 | c.2577C>G p.L859= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as COSV65991305; called by muse, mutect2, varscan2
- INHA | c.813C>T p.F271= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV54725366; called by muse, mutect2, varscan2
- ITPR2 | c.498C>T p.F166= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs563917550, COSV54385515; called by muse, mutect2, varscan2
- KCNH5 | c.1626G>C p.R542= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs777044154, COSV59768217, COSV59770374; called by mutect2, varscan2
- LGR5 | c.57G>A p.A19= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs147257938, COSV57003635; called by muse, mutect2, varscan2
- MIF | c.6G>A p.P2= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs754279861, COSV53158985; called by muse, mutect2, varscan2
- MTSS1 | c.1377G>A p.R459= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1258693159, COSV61498648; called by muse, mutect2, varscan2
- MUC16 | c.19650G>A p.V6550= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV67479052; called by muse, mutect2, varscan2
- MYO1E | c.1335C>T p.I445= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs200815044, COSV55690417; called by muse, mutect2, varscan2
- NFATC2 | c.2046G>A p.K682= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV65358597; called by muse, mutect2, varscan2
- NSUN5 | c.345G>A p.V115= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1221453560, COSV53092781; called by muse, mutect2, varscan2
- NUDT17 | c.834C>T p.V278= | Silent (SNP) | VAF 313/825 reads (38%) | catalogued as COSV57907909; called by muse, mutect2, varscan2
- NUP205 | c.531G>C p.L177= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53662917; called by muse, mutect2, varscan2
- NUP205 | c.1011G>A p.L337= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1204766003, COSV53658010, COSV53662926; called by muse, mutect2, varscan2
- OR2G6 | c.459C>T p.L153= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV58575237; called by muse, mutect2, varscan2
- OR4D6 | c.486G>A p.L162= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV55660333; called by muse, mutect2, varscan2
- OR6C6 | c.351C>T p.S117= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV64455958; called by muse, mutect2
- PCDH19 | c.138G>A p.A46= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- PCSK9 | c.1314C>G p.P438= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV56163372; called by muse, mutect2, varscan2
- PDLIM2 | c.453C>T p.I151= (on ENST00000397760; = p.I401= on NM_021630.6) | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as COSV56134008, COSV56135416; called by muse, mutect2, varscan2
- PLCL2 | c.2799G>A p.L933= (on ENST00000615277 / NM_001144382.2; = p.L807= on NM_015184.5) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67623751; called by muse, mutect2
- PLEKHH1 | c.2364C>G p.L788= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV61285710; called by muse, mutect2, varscan2
- POM121C | c.3615C>G p.S1205= (on ENST00000607367; = p.S963= on NM_001099415.3) | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV57547658, COSV99992821, COSV99993058; called by muse, mutect2, varscan2
- RCAN2 | c.330C>G p.L110= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV57817700; called by muse, mutect2, varscan2
- ROS1 | c.18T>C p.C6= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1562401018, COSV63858459; called by muse, mutect2, varscan2
- RREB1 | c.3627C>T p.A1209= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs765867404, COSV58561539; called by muse, mutect2, varscan2
- RTEL1 | c.2814C>G p.L938= | Silent (SNP) | VAF 69/287 reads (24%) | catalogued as rs757150825, COSV58897800, COSV58900300; called by muse, mutect2, varscan2
- SAMHD1 | c.1725C>T p.L575= (on ENST00000262878 / NM_001363729.2; = p.L610= on NM_015474.4) | Silent (SNP) | VAF 96/273 reads (35%) | catalogued as COSV53431057; called by muse, mutect2, varscan2
- SDHAF3 | c.105G>A p.V35= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs749895347, COSV64491685; called by muse, mutect2, varscan2
- SLC25A2 | c.90C>T p.F30= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs782057188, COSV53403460; called by muse, mutect2, varscan2
- SLC36A3 | c.687G>A p.L229= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs745663323, COSV58857590; called by muse, mutect2, varscan2
- SLC43A3 | c.114G>A p.K38= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as COSV61450850; called by muse, mutect2, varscan2
- SLC5A1 | c.978C>T p.F326= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV56686609; called by muse, varscan2
- SMARCA4 | c.2376C>T p.L792= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs568699320, COSV60802566; ClinVar: likely benign; called by muse, mutect2, varscan2
- STK11IP | c.264C>G p.L88= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs368062862, COSV55246274; called by muse, mutect2, varscan2
- SV2A | c.66C>A p.V22= | Silent (SNP) | VAF 143/341 reads (42%) | catalogued as COSV64965395; called by muse, mutect2, varscan2
- SYNE2 | c.12957G>A p.L4319= | Silent (SNP) | VAF 33/57 reads (58%) | catalogued as COSV59959429; called by muse, mutect2, varscan2
- SYT2 | c.600G>A p.L200= | Silent (SNP) | VAF 164/249 reads (66%) | catalogued as rs1422893938, COSV66142530; called by muse, mutect2, varscan2
- TAF6 | c.471G>A p.Q157= | Silent (SNP) | VAF 104/363 reads (29%) | catalogued as rs1209209695, COSV59842567; called by muse, mutect2, varscan2
- TRANK1 | c.8109C>G p.V2703= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as rs533759323, COSV57157221; called by muse, mutect2, varscan2
- TRBJ2-4 | c.33G>A p.G11= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- TRIM59 | c.621C>T p.L207= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as COSV59087896; called by muse, mutect2, varscan2
- TTC30B | c.618A>G p.S206= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV68809668; called by muse, mutect2, varscan2
- VAV2 | c.297C>A p.L99= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV64083531; called by muse, mutect2, varscan2
- ZFHX3 | c.3303C>G p.L1101= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs375352831, COSV51726831; called by muse, mutect2
- ZNF28 | c.1824G>A p.K608= | Silent (SNP) | VAF 202/307 reads (66%) | catalogued as COSV60424354; called by muse, mutect2, varscan2
- ZNF670 | c.1002G>T p.V334= | Silent (SNP) | VAF 94/222 reads (42%) | catalogued as COSV63608199, COSV63608541; called by muse, mutect2, varscan2
- ZNF786 | c.789G>A p.T263= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs781740244, COSV60276401, COSV60277100; called by muse, mutect2, varscan2
- ZP4 | c.1257C>T p.I419= | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as rs1323826906, COSV63912764; called by muse, mutect2, varscan2
- CCDC144B | n.1995C>T | RNA (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- NF2 | c.1737+1425G>A | Intron (SNP) | VAF 114/306 reads (37%) | catalogued as rs1405141736, COSV58527223; called by muse, varscan2
- PKD1L2 | n.2933G>T | RNA (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- TK2 | c.31+134C>G | Intron (SNP) | VAF 21/40 reads (53%) | catalogued as COSV50451512; called by muse, mutect2
